Somatic mutation profile of cancer-model specimen HCM-CSHL-0381-C20-85A (3D Organoid; aliquot HCM-CSHL-0381-C20-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0381-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.8 years (17,107 days).
Specimen HCM-CSHL-0381-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39803575-7dda-4740-8d1e-6d843a3e472e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0381-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0381-C20-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dcda1ef-2e14-4012-966b-3c388bc6e576

The open-access MAF lists 134 somatic variants for this specimen: 103 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 29, Frame Shift Del 12, Nonsense Mutation 6, In Frame Del 4, Splice Region 2, Frame Shift Ins 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 200/446 reads (45%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 101/216 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 281/282 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC2 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1257093850; called by muse, mutect2
- ADCY2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 265/561 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769674129, COSV57864636; called by muse, mutect2, varscan2
- AGRN | c.4319C>T p.P1440L | Missense Mutation (SNP) | VAF 384/774 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as rs1013476257; called by muse, mutect2, varscan2
- AHNAK2 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 381/451 reads (84%) | SIFT tolerated (0.41); PolyPhen benign (0.292); catalogued as rs772936043, COSV100317494; called by muse, mutect2, varscan2
- AMDHD2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 340/676 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs763752753; called by muse, mutect2, varscan2
- AOC3 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 299/676 reads (44%) | catalogued as rs758238458, COSV57732549; called by muse, mutect2, varscan2
- APC | c.4304del p.R1435Kfs*38 | Frame Shift Del (DEL) | VAF 158/373 reads (42%) | catalogued as COSV57331063, COSV57332751; called by mutect2, pindel, varscan2
- ARHGAP33 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 220/536 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.677); catalogued as rs777134004; called by muse, mutect2, varscan2
- ARHGEF2 | c.2630G>C p.R877P (on ENST00000361247 / NM_001162383.2; = p.R849P on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/1092 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.774); catalogued as COSV58107754; called by muse, mutect2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 250/353 reads (71%) | catalogued as COSV62562863; called by mutect2, pindel, varscan2
- COL21A1 | c.1216T>A p.L406M | Missense Mutation (SNP) | VAF 150/281 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV55157436; called by muse, mutect2, varscan2
- CPN2 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 254/554 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1416554747; called by muse, mutect2, varscan2
- DEFB108B | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 142/527 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs151229532; called by muse, mutect2
- DMXL1 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201096718, COSV100224530; called by muse, mutect2, varscan2
- DMXL2 | c.5392del p.R1798Vfs*7 | Frame Shift Del (DEL) | VAF 16/176 reads (9%) | catalogued as COSV51852261; called by mutect2, varscan2
- GRM6 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 397/830 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs1193992490; called by muse, mutect2
- H2BC18 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 210/485 reads (43%) | catalogued as rs782079686; called by pindel, varscan2
- HS3ST3A1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 232/498 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs779968068; called by muse, varscan2
- KCND1 | c.389A>T p.D130V | Missense Mutation (SNP) | VAF 380/802 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54414730; called by muse, mutect2, varscan2
- KCNIP1 | c.358G>A p.E120K (on ENST00000411494 / NM_001034837.3; = p.E109K on NM_014592.4) | Missense Mutation (SNP) | VAF 145/357 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs550125684, COSV61089559; called by muse, mutect2, varscan2
- KIAA1586 | c.1828A>G p.I610V | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as rs776920348; called by muse, mutect2, varscan2
- LAMA3 | c.4546G>A p.A1516T | Missense Mutation (SNP) | VAF 231/231 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs776672532; called by muse, mutect2, varscan2
- LAMB2 | c.5081G>A p.R1694H | Missense Mutation (SNP) | VAF 222/583 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs758687310; called by muse, mutect2, varscan2
- LRRIQ3 | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63043534; called by muse, mutect2
- LRRIQ3 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | catalogued as rs376287445; called by muse, mutect2
- MAP2 | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52291213; called by muse, mutect2, varscan2
- MMRN2 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 480/934 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV64400404; called by muse, mutect2, varscan2
- MNS1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs747033452; called by muse, mutect2, varscan2
- NCAPG | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52269779; called by muse, mutect2, varscan2
- OR13D1 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV59513712; called by muse, mutect2
- OXTR | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 397/944 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs756453502; called by muse, mutect2, varscan2
- POMZP3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 128/554 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.818); catalogued as rs779256643; called by muse, mutect2, varscan2
- POU4F1 | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 44/703 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1185987234; called by muse, mutect2
- SCRIB | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 340/1439 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs760633347, COSV100254332; called by muse, mutect2, varscan2
- SENP1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs781395484; called by muse, mutect2
- TBC1D2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 200/530 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV59786021; called by muse, mutect2, varscan2
- UMODL1 | c.2270C>T p.S757L (on ENST00000408910 / NM_001004416.2; = p.S885L on NM_173568.3) | Missense Mutation (SNP) | VAF 259/554 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs765973844, COSV68571659; called by muse, mutect2, varscan2
- UTRN | c.8462C>G p.S2821C | Missense Mutation (SNP) | VAF 108/291 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV104422959; called by muse, mutect2, varscan2
- ZNF581 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 311/651 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1280303701; called by muse, mutect2, varscan2
- B2M | c.244_247del p.F82Ifs*20 | Frame Shift Del (DEL) | VAF 22/244 reads (9%) | called by mutect2, pindel
- BX276092.9 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 42/836 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); called by muse, mutect2
- CCDC157 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 336/336 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CDH23 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 35/618 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.767); called by muse, mutect2
- CLTC | c.1521dup p.V508Sfs*33 | Frame Shift Ins (INS) | VAF 47/129 reads (36%) | called by mutect2, pindel, varscan2
- CNNM2 | c.2446T>G p.L816V | Missense Mutation (SNP) | VAF 179/355 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CTNND1 | c.2227A>C p.N743H (on ENST00000399050 / NM_001085458.2; = p.N737H on NM_001331.3) | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CWF19L1 | c.1546del p.E516Kfs*37 | Frame Shift Del (DEL) | VAF 168/533 reads (32%) | called by mutect2, pindel, varscan2
- DAB2 | c.2143_2151del p.P715_P717del | In Frame Del (DEL) | VAF 40/257 reads (16%) | called by pindel, varscan2*
- DTNB | c.899_902del p.S300Mfs*33 | Frame Shift Del (DEL) | VAF 71/244 reads (29%) | called by mutect2, pindel, varscan2
- EEF2K | c.695_701del p.I232Tfs*20 | Frame Shift Del (DEL) | VAF 218/533 reads (41%) | called by mutect2, pindel, varscan2
- EFNA4 | c.467G>T p.R156M | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.291); called by muse, mutect2
- ERAL1 | c.395A>C p.Q132P | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- EYA2 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 68/982 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2
- FAM24B | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 224/458 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FAT2 | c.4250A>C p.N1417T | Missense Mutation (SNP) | VAF 170/530 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT4 | c.1616del p.G539Afs*12 | Frame Shift Del (DEL) | VAF 140/428 reads (33%) | called by mutect2, pindel, varscan2
- FBN2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 147/297 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF6 | c.460_477del p.Q154_F159del | In Frame Del (DEL) | VAF 93/377 reads (25%) | called by mutect2, pindel, varscan2
- FREM2 | c.8375_8378del p.P2792Hfs*21 | Frame Shift Del (DEL) | VAF 109/262 reads (42%) | called by mutect2, pindel, varscan2
- GOLGA6L6 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 99/127 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- HMGN5 | c.798T>A p.D266E | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA11 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 226/227 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGB7 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 52/674 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC25 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 363/730 reads (50%) | called by muse, mutect2, varscan2
- LRRN4 | c.766C>G p.Q256E | Missense Mutation (SNP) | VAF 61/349 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEB5 | c.483A>G p.I161M | Missense Mutation (SNP) | VAF 24/614 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); called by muse, mutect2
- MAP3K5 | c.4047_4055del p.K1350_L1352del | In Frame Del (DEL) | VAF 64/164 reads (39%) | called by mutect2, pindel, varscan2
- MERTK | c.2973del p.S992Qfs*7 | Frame Shift Del (DEL) | VAF 128/410 reads (31%) | called by mutect2, pindel, varscan2
- MPDZ | c.905T>G p.I302S | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSX2 | c.378A>T p.P126= | Splice Region (SNP) | VAF 205/505 reads (41%) | called by muse, mutect2, varscan2
- NLGN4X | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 324/627 reads (52%) | called by muse, mutect2, varscan2
- NOP14 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 172/408 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUP133 | c.719T>C p.I240T | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2
- OR5F1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- OR6N2 | c.452G>C p.C151S | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.193); called by muse, mutect2
- PDCD11 | c.3092A>G p.H1031R | Missense Mutation (SNP) | VAF 21/680 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- PDGFC | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFDN2 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 377/853 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2670G>T p.M890I | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PXDNL | c.2689T>C p.S897P | Missense Mutation (SNP) | VAF 43/693 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASAL2 | c.2872A>T p.R958W | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF128 | c.225_256del p.Y75* | Frame Shift Del (DEL) | VAF 73/322 reads (23%) | called by mutect2, pindel, varscan2
- RPRD1B | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 122/471 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RYR1 | c.11230G>A p.A3744T | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- SASH1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 163/335 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- SASH1 | c.2017T>G p.L673V | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SF1 | c.452A>C p.N151T | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC35G1 | c.701T>C p.F234S (on ENST00000427197 / NM_001134658.3; = p.F233S on NM_153226.4) | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.034); called by muse, mutect2
- SLC7A13 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 172/591 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- STK38 | c.371del p.D124Vfs*18 | Frame Shift Del (DEL) | VAF 78/180 reads (43%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 218/473 reads (46%) | called by muse, mutect2, varscan2
- TG | c.3273G>T p.Q1091H | Missense Mutation (SNP) | VAF 175/825 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- THBS3 | c.2780T>C p.I927T | Missense Mutation (SNP) | VAF 251/508 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRPC3 | c.2176A>G p.I726V (on ENST00000379645 / NM_001366479.2; = p.I653V on NM_003305.2) | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUT1 | c.45dup p.F16Vfs*17 | Frame Shift Ins (INS) | VAF 270/538 reads (50%) | called by mutect2, varscan2
- UBR5 | c.5279C>G p.T1760R | Missense Mutation (SNP) | VAF 175/752 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- VWF | c.6978G>C p.V2326= | Splice Region (SNP) | VAF 137/308 reads (44%) | called by muse, mutect2, varscan2
- WDR87 | c.1737G>C p.L579F | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF101 | c.1081A>C p.S361R | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZNF429 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AGAP5 | c.1146C>A p.S382= | Silent (SNP) | VAF 80/1144 reads (7%) | called by muse, mutect2
- AGTR1 | c.996A>C p.T332= | Silent (SNP) | VAF 104/270 reads (39%) | called by muse, varscan2
- ARAP3 | c.2517C>T p.G839= | Silent (SNP) | VAF 371/823 reads (45%) | called by muse, mutect2, varscan2
- BBX | c.621C>A p.G207= | Silent (SNP) | VAF 99/267 reads (37%) | called by muse, mutect2, varscan2
- C10orf95 | c.396C>T p.G132= | Silent (SNP) | VAF 121/1105 reads (11%) | catalogued as rs974414601; called by muse, mutect2, varscan2
- CASP3 | c.681C>T p.A227= | Silent (SNP) | VAF 118/262 reads (45%) | catalogued as rs977632962, COSV57725842; called by muse, mutect2, varscan2
- COL5A2 | c.4194C>A p.S1398= | Silent (SNP) | VAF 106/222 reads (48%) | called by muse, mutect2, varscan2
- COL5A2 | c.2043T>C p.G681= | Silent (SNP) | VAF 86/220 reads (39%) | catalogued as rs1553515128, COSV66408961; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIP2A | c.1008G>A p.L336= | Silent (SNP) | VAF 359/727 reads (49%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.9252T>C p.T3084= | Silent (SNP) | VAF 89/233 reads (38%) | called by muse, mutect2, varscan2
- FREM2 | c.4608C>A p.V1536= | Silent (SNP) | VAF 17/447 reads (4%) | called by muse, mutect2
- GAA | c.2658G>T p.V886= | Silent (SNP) | VAF 209/449 reads (47%) | catalogued as COSV100163451; called by muse, mutect2, varscan2
- GRM1 | c.2976G>A p.P992= | Silent (SNP) | VAF 355/737 reads (48%) | catalogued as rs200487711, COSV51124415, COSV51268729; called by muse, mutect2, varscan2
- GSTK1 | c.672C>G p.A224= | Silent (SNP) | VAF 177/383 reads (46%) | called by muse, mutect2, varscan2
- HOXC9 | c.270G>A p.T90= | Silent (SNP) | VAF 599/1172 reads (51%) | catalogued as COSV57717066; called by muse, mutect2, varscan2
- IGHD4-17 | c.16C>T p.*6= | Silent (SNP) | VAF 50/288 reads (17%) | called by muse, mutect2, varscan2
- MYO7B | c.2649G>A p.P883= | Silent (SNP) | VAF 196/434 reads (45%) | catalogued as rs201458881; called by muse, mutect2, varscan2
- NWD2 | c.4875C>T p.S1625= | Silent (SNP) | VAF 152/375 reads (41%) | called by muse, mutect2, varscan2
- OLFML2A | c.1044G>A p.V348= | Silent (SNP) | VAF 390/774 reads (50%) | catalogued as rs1488787045; called by muse, mutect2, varscan2
- OR12D2 | c.81G>A p.V27= | Silent (SNP) | VAF 174/409 reads (43%) | called by muse, mutect2, varscan2
- PHYHD1 | c.693A>T p.P231= (on ENST00000372592 / NM_001100876.2; = p.Q224L on NM_174933.4) | Silent (SNP) | VAF 23/203 reads (11%) | called by muse, mutect2
- RPRD2 | c.2724T>G p.S908= | Silent (SNP) | VAF 240/500 reads (48%) | called by muse, mutect2, varscan2
- SMARCC1 | c.423C>T p.N141= | Silent (SNP) | VAF 84/223 reads (38%) | called by muse, mutect2, varscan2
- SPTA1 | c.4419G>A p.T1473= | Silent (SNP) | VAF 142/328 reads (43%) | catalogued as rs771135166; called by muse, mutect2, varscan2
- UFL1 | c.681C>T p.S227= | Silent (SNP) | VAF 121/285 reads (42%) | called by muse, mutect2, varscan2
- VSIG10L2 | c.1701C>T p.D567= | Silent (SNP) | VAF 585/586 reads (100%) | called by muse, mutect2, varscan2
- WASHC2C | c.2091C>T p.S697= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as rs577995300; called by muse, mutect2, varscan2
- WASHC5 | c.2253C>T p.F751= | Silent (SNP) | VAF 18/578 reads (3%) | catalogued as COSV100573174; called by muse, mutect2
- ZYG11B | c.1521A>G p.Q507= | Silent (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2619C>T | Intron (SNP) | VAF 479/902 reads (53%) | catalogued as COSV56002080; called by muse, mutect2, varscan2
- CXCL11 | c.*379T>A | 3'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
